Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A70Z, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A70Z-01A (Primary Tumor).

[page 1 of 5]
Observation Date and Time

Entry Date

Result Narrative

(NOTE)

Surgical Pathology Report

Patient Name: ---

Accession #: ---

Med. Rec #: ---

Submitting Physician: ---

--- Clinical History ---

Left parietal temporal lobe lesion.

ADDENDA:

Addendum added: [REDACTED]

Addendum added: [REDACTED]

---Final Pathologic Diagnosis---

A. Left temporal tumor, resection:
- High grade glioma. See comment.

B. Left temporal tumor, resection:
- High grade glioma. See comment

Comment: Assays for 1p and 19q deletions are pending and the lineage of the tumor (anaplastic oligodendroglioma vs mixed oligoastrocytoma) will be determined once the result is available.

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the

at --- and are not required to

in the

ICD O-3
Oligoastrocytoma, grade III
9/382/13
Site CCF
4 Brain, supratentorial NOS
C71.0
path
④ Brain, temporal lobe
C71.2
JW 8/22/13

[page 2 of 5]
[REDACTED]

have nor do they have FDA approval.

[REDACTED]

---Addendum Report---

Addendum

Status: Signed Out

Detection of 1p36 and 19q by LSIe 1p36/LSI 1q25 and LSI 19q13/19p13
Dual-Color Probe Sets

[REDACTED] Patient Name:
Source of case --- Patient MRN:
Block used B4
Tissue fixation formalin-fixed tissue
Tissue source Breast

RESULTS

Ratio of 0.84 Cell count of 1p/1q: 177
Ratio of 0.82 Cell count of 19q/19p: 128

Interpretation of Results: A) 1p no loss; B) 19q no loss

Interpretation of findings:

A) (positive) The majority of tumors cells displayed 2 control chromosome 1q25 signals and 1 chromosome 1p36 signals (locus of interest). The ratio of 1p36/1q25 is <0.8 . The results are consistent with the loss of 1p36 locus of interest. B) (negative) The majority of tumors cells displayed 2 to 3 control chromosome 19p13 signals and 2 to 3 chromosome 19q13 signals (locus of interest), and the ratio of 19q13/19p13 Ratio was >0.8 . The results are consistent with no loss of the 19q13 locus of interest.

Number of Observers: 2
Test Interpreted By: ---

Comments

The resultant FISH section/slide is scanned by a trained licensed medical technologist and analyzed using a FDA-approved, validated semi-automated scanning imaging

workstation () and accompanying imaging analysis software

The resultant FISH section/slide is then presented to the

[page 3 of 5]
[REDACTED]

interpreting Pathologist, who will
reviews the FISH results from and compares them to the results
manually observed under Fluorescence Microscope. Therefore the
ratio is enumerated

by computer-aided counting as well as manual counting.

Interpretation of Test

The ratio for probe set 1 is derived by dividing the total number of
LSI 1p36 signals by the total number of LSI 1q25 signals in at least 20
interphase nuclei with

nonoverlapping nuclei in the neoplastic glial cells. Cells with no
signals or with signals of only one color are disregarded. The ratio for
probe set 2 is derived by dividing the

total number of LSI 19q13 signals by the total number of LSI 19p13
signals in at least 2 sets of 20 interphase nuclei with nonoverlapping
nuclei in the neoplastic glial cells at

two different areas of the sample. Cells with no signals or with
signals of only one color are disregarded. Reference ranges for our
laboratory for allelic loss versus no

allelic loss were established by evaluating both probe sets in a
series of 40 normal cases from 10 different organs. For both probe set 1
and 2 a ratio of less than 0.80 taken

from at least 2 sets of 20 interphase nuclei at 2 different areas with
nonoverlapping nuclei is consistent with allelic loss. FISH and H&E
stained slides have been reviewed

by the interpreting pathologist.

Limitations

ANALYTE SPECIFIC REAGENT: The use of one or more reagents in the above
tests is regulated as an analyte specific reagent (ASR). These tests were
developed and

their performance characteristics determined by the

They have not been

cleared by the US Food and

Drug Administration. The FDA has determined that such clearance or
approval is not necessary.

[REDACTED]

Addendum

Status: Signed Out

A and B: Left temporal lobe, resection:

- Anaplastic mixed oligastrocytoma (WHO grade III).

Assays failed to detect deletions of 1p and 19q loci.

[page 4 of 5]
---INTRAOPERATIVE CONSULTATION DIAGNOSIS:---

AF1. Left temporal tumor: (FROZEN SECTION PERFORMED)
- Infiltrating glial neoplasm.

Note: There is no doctor listed; however, a time of indicated.

Examining pathologist:---

---MICROSCOPIC:---

Sections reveal an infiltrating cellular neoplasm composed of glial elements with areas of cells having atypical and elongated nuclei consistent with astrocytes; however, in most of the areas, cells with rounder configuration, groups of minigemistocytes and background slender vasculature are identified. Also, frequent mitotic figures, microvascular proliferations, and foci of necrosis including geographic necrosis are noted. Immunostain for GFAP is positive in many cells and a Ki-67 stain shows a proliferation index of about 20-25%, as determined by manual quantification.

---SPECIMEN(S) RECEIVED:---

A: Brain BX
B: Brain BX

---GROSS DESCRIPTION:---

The specimens are received in two properly labeled containers with the patient's name and accession number, one of which was submitted for frozen sectioning.

A. The specimen is designated "left temporal tumor" and consists of a 0.6 x 0.5 x 0.4 cm aggregate of soft tissue. A touch prep was performed and the entire specimen was submitted for frozen sectioning, resubmitted as received in cassette AF1. [REDACTED]

[page 5 of 5]
B. The specimen is designated "left temporal tumor" and consists of a 35.05 gram, 5.5 x 5.2 x 1.5 cm portion of brain tissue which ranges from gray-tan to pink-red. A 4.6 x 3.6 cm area of pink-red disruption and discoloration is identified along one surface, with the opposing surface bearing a 5.0 x 4.3 cm area of shaggy, disrupted, white-tan discoloration. Serial sectioning reveals white-gray to tan-brown to deep red, focally hemorrhagic cut surfaces with the irregularity measuring 5.3 x 4.9 x 1.3 cm. The grossly uninvolved parenchyma is white-gray to [REDACTED] with a distinguishable border between white and gray matter. [REDACTED]

Summary of Cassettes: B1-5, random sections through softened area of discoloration and hemorrhage; B6, grossly uninvolved tissue

Lab Use Only: [REDACTED]

Gross description by: ---

hw 7/29/13

Source: NCI Genomic Data Commons file 9fc0e280-5815-4e89-90e7-edaea13e2630 (TCGA-FG-A70Z.E2908E5D-A017-41AE-AF5F-367A1D4C868B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).